Surgical pathology report (de-identified scan), TCGA case TCGA-EI-6509, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-EI-6509-01A (Primary Tumor).

Examination: Histopathological examination

Material: **1. Multiple organ resection – rectum and sigmoid colon**

TCGA – EI – 6509

Physician in charge:

Material collected on:

Material received on:

Expected time of examination

Clinical diagnosis: **Cancer of the sigmoid colon. Lesion on the rectum-sigmoid boundary.**

Examination performed on

Macroscopic description:

18 cm length of the large intestine with fat tissue of 8 cm in thickness. Ulcerous tumour sized 4 x 4 x 1.2 cm found in the mucosa. The lesion surrounds 80% of the intestine circumference and narrows its cross section, located 5 cm from one of the incision lines and 9 cm from the opposite one. Minimum side margin is 6 cm.

Microscopic description:

Adenocarcinoma tubulopapillare (G2).

Infiltratio carcinomatosa et tunicae muscularis mucosae, telae submucosae tunicae muscularis propriae et telae adiposae.

Incision lines free of neoplastic lesions.

Metastases carcinomatosae in lymphonodis (No VII/X).

Infiltratio carcinomatosa capsulae lymphonodorum et telae adiposae perinodalis.

Emboliae carcinomatosae.

Histopathological diagnosis:

Adenocarcinoma tubulopapillare recti. Tubulopapillar adenocarcinoma of the colon

Metastases carcinomatosae in lymphonodis regionalis (No VII/X). Cancer metastases in regional lymph nodes.

(G2, Dukes C, Astler-Coller C2, pT3, pN2b, R0).

Source: NCI Genomic Data Commons file 8640e051-0c73-40a5-bcf0-5c33a49bdc1c (TCGA-EI-6509.B6AD21A1-9BD4-43C6-90AE-16277A76B5EA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).